Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7P6, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7P6-01A (Primary Tumor).

[page 1 of 3]
Age: years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession No:
Physician:
Copy to:

Surgical Pathology Report

Clinical Information

year old male with mesothelioma; Left Thoracotomy, Pleurectomy, PDT, Bronchoscopy

Final Diagnosis

1. RIB:

Benign lamellar bone with trilinear bone marrow formation.
No tumor seen.

2. DIAPHRAGM MUSCLE:

Skeletal muscle and fat, no tumor seen.

3. PERICARDIUM:

Multiple fragments of soft tissue with presence of mesothelioma, epithelial type.

4. DIAPHRAGM:

Fibrofatty soft tissue with focal areas of acute inflammation and small islands of malignant mesothelioma.

5. LUNG:

Section of lung parenchyma, no tumor seen.

6. LEVEL 5:

Section of lymph node, no tumor seen.

Section of fibrofatty soft tissue with rare single detached malignant mesothelial cells.

7. LEVEL 9:

Sections of lymph node, no tumor seen.

Fibrofatty soft tissue with prominent acute inflammation.

8. LEVEL 7:

Sections of lymph node with presence of malignant mesothelioma with extra nodular extension.

9. PLEURA:

Sections of pleura with extensive malignant mesothelioma, epithelioid type with focal vascular invasion and focal areas of underlying pulmonary parenchyma with involvement by malignant mesothelioma (9H).

10. POSTERIOR INTERCOSTAL:

ICD-O-3
Mesothelioma, epithelial NOS
9052/3
Site: Pleura NOS
C38.4
9/24/13

Name
M

Page 1 of 3

[page 2 of 3]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

Sections of lymph node with presence of malignant mesothelioma.

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date

Note

Mesothelioma

Pleurectomy left

Site: Left

Histologic Type

Epithelioid (epithelial) mesothelioma

Margins

Cannot be assessed

Lymph nodes

Specify: Number examined: 5
Number involved: 2

Pathologic Staging (pT2 N2 Mx)

Gross Description

The specimen is received in 10 parts in formalin in a container labeled with the patient's name and medical record number.

Specimen #1 is designated "Rib" and consists of two portions of yellow-tan, focally hemorrhagic trabeculated and easily fragmented bone measuring 2.5 and 1.1 cm in greatest dimension. The specimen is entirely submitted in cassette 1A following decalcification.

Name: [REDACTED]
MR: [REDACTED]

[page 3 of 3]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No.:
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #2 is designated "Diaphragm Muscle" and consists of a 2.5 x 1.1 x 1.0 cm portion of red-brown, beefy muscle. The specimen is submitted entirely in cassette 2A.

Specimen #3 is designated "Pericardium" and consists of multiple portions of gray-brown elastic soft tissue that are focally thickened measuring 6.0 x 5.5 x 1.5 cm in aggregate. The specimen is representatively submitted in cassettes 3A through 3F.

Specimen #4 is designated "Diaphragm" and consists of a 3.7 x 1.1 x 0.6 cm portion of red-brown soft tissue. The specimen is serially sectioned and submitted entirely in cassettes 4A and 4B.

Specimen #5 is designated "Lung" and consists of a 3.0 x 1.1 x 0.6 cm portion of gray-tan soft tissue. The specimen is serially sectioned and submitted entirely in cassette 5A.

Specimen #6 is designated "Level 5" and consists of two gray-tan portions of soft tissue measuring 1.2 and 1.0 cm in greatest dimension. The specimen is submitted in toto in cassette 6A.

Specimen #7 is designated "Level 9" and consists of two gray-tan to yellow portions of soft tissue measuring 0.6 and 0.9 cm in greatest dimension. The specimen is submitted in toto in cassette 7A.

Specimen #8 is designated "Level 7" and consists of a 1.9 x 0.8 x 0.3 cm portion of gray-tan soft tissue. The specimen is bisected and submitted in toto in cassette 8A.

Specimen #9 is designated "Pleura" and consists of a 845.4 white-tan and diffusely thickened and bosselated portion of soft tissue measuring 24.0 x 15.0 x 0.9 cm. The specimen is representatively submitted in cassettes 9A through 9J.

Specimen #10 is designated "Posterior Intercostal" and consists of three portions of yellow-tan, lobulated adipose tissue measuring 0.6, 1.0 and 1.1 cm in greatest dimension. The specimen is submitted in toto in cassette 10A.

Dictated by:

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

Page 3 of 3

Source: NCI Genomic Data Commons file e8af7cd3-add7-4288-b1a1-14e36750f7d8 (TCGA-TS-A7P6.D2069A48-E08B-4BD0-ACFE-E380345970B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).